Surgical pathology report (de-identified scan), TCGA case TCGA-66-2783, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2783-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Pleura, among others

Clinical diagnosis and question

Colliquating process S9/10 left and S6 right.

REPORT ON FINDINGS**Macroscopy**

- 1.) Basal group: inflated, fixed lower lobe (basal group) measuring 15 x 11.5 cm at the base, up to 10 cm, central bronchus resection plane located at the level of the branch into the segmental bronchi. Two rather horizontal staple suture lines of 4 and 5 cm in length run cranial to the hilus. Ventral to the hilus a staple suture line runs in an arc for a length of 5.5 cm. Visceral pleura shows partly reticulate blackish pigmentation, with lateral and basal patches or foci of pale material. In S9 and 10 is a peripheral/intermediate tumor with an arcuate configuration, max. 5.7 cm in size, showing marked central colliquation and extending to the pleura in the basal region, central spread to within about 1 cm of the bifurcation in B9 and 10. In the marginal area, especially in the basal sections, the lung parenchyma shows marked compaction and solidification with a pale brown color. In the medial subpleural region in S8 is a 0.9 cm node showing whitish section surfaces with a blackish pigmented margin suggestive of a tumor. Rest of parenchyma partly patchy blackish pigmentation, focal rarefaction with formation of lacunae of max. 0.2 cm.
- 2.) Lobar LN (station 12) upper lobe: two node parts about 1 cm in size.
- 3.) Lobar LN (station 12) lower lobe: 1.5 cm node part.
- 4.) Lobar LN (station 12) left: two node parts each about 0.5 cm in size.
- 5.) Interlobar LN (station 11) left: 0.7 cm node part.
- 6.) Pulmonary ligament LN (station 9) 0.5 cm node with some surrounding tissue.

Examined:

- 1.) a: Rapid section remains, b: tumor central with B9+10, c: 3 sections of tumor with pleura, d: tumor with solidified surrounding parenchyma, e: subpleural node S8 (halved), f: bronchus, resection margins of vessels (tangential),
- 2.) - 6.) Al material,
- 11 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

Microscopy

Re 1.) Immediate intraoperative evaluation (): necrotic older large-cell solid carcinoma, possibly squamous cell carcinoma.

Description of histological and cytological findings omitted for capacity reasons.

[page 2 of 2]
EVALUATION

Primary diagnosis/diagnoses:

Intermediate to peripheral, bronchopulmonary, histologically poorly differentiated, nonkeratinizing squamous cell carcinoma of the left lower pulmonary lobe located in S9

TNM classification according to this picture pT2 pN1 pMX R0, stage IIB

C 34.3; M 8070/3.

Secondary diagnosis/diagnoses:

Tumor necroses. Active fibrin-rich chronic granulating pneumonia in the tumor environment associated with active fibrin-rich and chronic granulating visceral pleuritis (sample 1.)). Lymph nodes with reactive lesions and anthracotic pigment deposits (samples 2.) - 6.)).

Remark/addendum:

The subpleural intrapulmonary lymph node in S8 is metastatically involved and explains the pN1 category. There is no discernible infiltration of the visceral pleura. The resection margin of the bronchus and vessels and also the lymph nodes of samples 2.) - 6.) are tumor-free.

Material examined:

Pleural aspirate

Clinical diagnosis and question

Colliquating process S9/10 left and S6 right.

REPORT ON FINDINGS

Macroscopy

3 mL, amber-colored.

Examined: two smear preparations.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

EVALUATION

Primary diagnosis/diagnoses:

Pleural effusion aspirate with a few, in part degeneratively changed mesothelial cells or macrophages

Secondary diagnosis/diagnoses:

Accumulation of leukocytes

Remark/addendum:

No cell(s) suggestive of malignancy.

Source: NCI Genomic Data Commons file 420afde2-689a-4199-a6ca-8c3b4e515308 (TCGA-66-2783.15CDE679-E737-4F03-AE8B-CE80908FEA17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).